MMRF case MMRF_2111 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0a6cb426-5baf-415c-9583-2b5908cf6357

Demographics
Sex at birth: female; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.5 years (22,107 days); ISS stage: II; Days to last known disease status: 911 days (2.5 years); Days to last follow up: 911 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 153 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 327 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22: M Protein 2.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 133 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 34.3 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 3.51 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 8.33 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 8.8 g/dL; Glucose 6.16 mmol/L; C-Reactive Protein 0.27 mg/dL.
- Day 63 (ECOG 0): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 2.03 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 6.71 mmol/L.
- Day 190 (ECOG 0): M Protein 0.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.75 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.05 mmol/L.
- Day 257 (ECOG 0): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 6.05 mmol/L.
- Day 358 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 467: M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 417 ×10⁹/L.
- Day 532 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.94 mmol/L.
- Day 629: M Protein 0.2 g/dL; Hemoglobin 6.82 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 241 ×10⁹/L.
- Day 693: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.04 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Glucose 7.37 mmol/L.
- Day 832: M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.96 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.91 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 379 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 1.9 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 883: Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 208 ×10⁹/L.
- Day 911 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -22: Weight: 80 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2111_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_2111_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
